Somatic mutation profile of tumor specimen MMRF_2124_1_BM_CD138pos (aliquot MMRF_2124_1_BM_CD138pos_T1_KHS5U_L08709) from MMRF case MMRF_2124, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 55.2 years (20,165 days).
Specimen MMRF_2124_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) af114230-b552-45f0-a517-6c39c0a6ab7b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2124_1_PB_CD3pos (Blood Derived Normal), aliquot MMRF_2124_1_PB_CD3pos_C2_KHS5U_L08708; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c273aa70-e3d5-48fb-a3b6-cfba79ce6b30

The open-access MAF lists 177 somatic variants for this specimen: 58 protein-altering or splice-affecting, 22 silent, 97 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 54, Missense Mutation 53, Intron 29, Silent 22, 5'UTR 9, RNA 3, Splice Region 3, 3'Flank 1, 5'Flank 1, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EED | c.904A>G p.R302G | Missense Mutation (SNP) | VAF 56/170 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs1131692175, COSV54553219; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 120/321 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: not provided / pathogenic; called by muse, varscan2
- AFF4 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 90/268 reads (34%) | SIFT tolerated (0.5); PolyPhen benign (0.062); catalogued as COSV99535219; called by muse, mutect2, varscan2
- CCDC181 | c.1079G>T p.R360L | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as COSV63155897; called by muse, mutect2, varscan2
- COL22A1 | c.3227C>T p.P1076L | Missense Mutation (SNP) | VAF 75/284 reads (26%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as COSV57324892; called by muse, mutect2, varscan2
- COL6A3 | c.415G>A p.G139S | Missense Mutation (SNP) | VAF 92/186 reads (49%) | SIFT tolerated (0.88); PolyPhen benign (0.001); catalogued as rs749386499, COSV55098376; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH7 | c.983T>C p.L328P | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV100415983; called by muse, mutect2, varscan2
- DYNC2I1 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.978); catalogued as rs763544882; called by muse, mutect2, varscan2
- EGLN1 | c.586G>C p.E196Q | Missense Mutation (SNP) | VAF 79/428 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.092); catalogued as COSV100791176; called by muse, mutect2, varscan2
- ELAVL3 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.114); catalogued as rs1407899639, COSV63648569; called by muse, mutect2
- EZH2 | c.839C>G p.S280C | Missense Mutation (SNP) | VAF 26/224 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57464823; called by muse, mutect2, varscan2
- IGKV4-1 | c.87C>G p.D29E | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.65); PolyPhen benign (0.129); catalogued as rs370905182; called by muse, varscan2
- IKBKB | c.511A>G p.K171E | Missense Mutation (SNP) | VAF 217/306 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1217007648, COSV60595911, COSV60598768; called by muse, mutect2, varscan2
- IL1R1 | c.1117G>A p.D373N | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT tolerated (0.51); PolyPhen benign (0.031); catalogued as rs769820748; called by muse, mutect2, varscan2
- KIAA0232 | c.4109C>T p.S1370L | Missense Mutation (SNP) | VAF 73/153 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.058); catalogued as rs767625358; called by muse, mutect2, varscan2
- KRBA1 | c.1639G>A p.E547K | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs1319605185, COSV99752607; called by muse, mutect2, varscan2
- PAPPA | c.1748G>A p.C583Y | Missense Mutation (SNP) | VAF 90/267 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60279374; called by muse, mutect2, varscan2
- PAQR8 | c.537C>G p.F179L | Missense Mutation (SNP) | VAF 43/128 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62442061; called by muse, mutect2, varscan2
- PDE2A | c.1360-7C>G | Splice Region (SNP) | VAF 16/281 reads (6%) | catalogued as rs1320130197; called by muse, mutect2
- PNRC1 | c.619G>C p.E207Q | Missense Mutation (SNP) | VAF 46/561 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as rs1333507341; called by muse, mutect2
- RHAG | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 16/497 reads (3%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV57704985; called by muse, mutect2
- SERPINB3 | c.178G>A p.D60N | Missense Mutation (SNP) | VAF 160/194 reads (82%) | SIFT tolerated (0.99); PolyPhen benign (0.001); catalogued as rs772500410; called by muse, mutect2, varscan2
- SLC22A6 | c.1397G>A p.R466Q | Missense Mutation (SNP) | VAF 44/92 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs750411183, COSV100842881; called by muse, mutect2, varscan2
- SNX22 | c.160-1G>A p.X54_splice | Splice Site (SNP) | VAF 11/242 reads (5%) | catalogued as COSV55520788; called by muse, mutect2
- TANK | c.967C>G p.L323V | Missense Mutation (SNP) | VAF 155/471 reads (33%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV52045282; called by muse, mutect2, varscan2
- UQCRFS1 | c.23C>T p.S8L | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as rs978580474; called by muse, mutect2, varscan2
- WDR33 | c.2702C>T p.P901L | Missense Mutation (SNP) | VAF 14/258 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); catalogued as rs1178275780; called by muse, mutect2
- ZNF337 | c.2242G>A p.E748K | Missense Mutation (SNP) | VAF 12/186 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53322704; called by muse, mutect2
- ATF6B | c.1768G>C p.D590H | Missense Mutation (SNP) | VAF 99/220 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BCL7B | c.437-3C>T | Splice Region (SNP) | VAF 20/233 reads (9%) | called by muse, mutect2
- C12orf29 | c.752G>A p.G251E | Missense Mutation (SNP) | VAF 106/293 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCN2 | c.743A>G p.E248G | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- DCUN1D4 | c.43C>T p.H15Y | Missense Mutation (SNP) | VAF 8/186 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.775); called by muse, mutect2
- DHX9 | c.1297G>A p.D433N | Missense Mutation (SNP) | VAF 134/459 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.001); called by muse, varscan2
- F8 | c.5083G>A p.D1695N | Missense Mutation (SNP) | VAF 29/193 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- FBN1 | c.3324G>A p.M1108I | Missense Mutation (SNP) | VAF 47/113 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- FILIP1 | c.1595A>T p.N532I | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- FOXL2NB | c.379C>A p.P127T | Missense Mutation (SNP) | VAF 51/142 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- GPR158 | c.3437C>G p.S1146C | Missense Mutation (SNP) | VAF 41/159 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- GUCA2A | c.121G>C p.D41H | Missense Mutation (SNP) | VAF 5/95 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.012); called by muse, mutect2
- HLA-F | c.64+3G>T | Splice Region (SNP) | VAF 28/101 reads (28%) | called by muse, mutect2, varscan2
- HS3ST4 | c.68C>T p.P23L | Missense Mutation (SNP) | VAF 40/185 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- KCP | c.523G>C p.E175Q | Missense Mutation (SNP) | VAF 47/179 reads (26%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- L3MBTL2 | c.1748G>A p.C583Y | Missense Mutation (SNP) | VAF 24/359 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.202); called by muse, mutect2
- LRRC30 | c.467C>T p.P156L | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- LUZP4 | c.239G>A p.R80K | Missense Mutation (SNP) | VAF 24/150 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- MAT1A | c.77G>T p.G26V | Missense Mutation (SNP) | VAF 53/161 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYPN | c.3041A>G p.D1014G | Missense Mutation (SNP) | VAF 102/214 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NCAPD3 | c.2255C>G p.S752* | Nonsense Mutation (SNP) | VAF 16/355 reads (5%) | called by muse, mutect2
- NEIL3 | c.1462G>A p.E488K | Missense Mutation (SNP) | VAF 64/181 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NKAPD1 | c.469C>T p.H157Y (on ENST00000280352 / NM_001082970.2; = p.H158Y on NM_018195.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 84/255 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.898); called by mutect2, varscan2
- PRKAR2A | c.538G>C p.E180Q | Missense Mutation (SNP) | VAF 224/508 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- PRRC2C | c.7654C>T p.L2552F (on ENST00000367742; = p.L2550F on NM_015172.4) | Missense Mutation (SNP) | VAF 36/125 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- SIRT1 | c.1690G>C p.D564H | Missense Mutation (SNP) | VAF 13/240 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.01); called by muse, mutect2
- SOBP | c.1447G>A p.A483T | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- ZNF284 | c.1358G>C p.R453T | Missense Mutation (SNP) | VAF 100/226 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- ZNF429 | c.208A>C p.M70L | Missense Mutation (SNP) | VAF 50/449 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- ZNF430 | c.70C>T p.L24F | Missense Mutation (SNP) | VAF 72/161 reads (45%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAMTS18 | c.774G>A p.K258= | Silent (SNP) | VAF 22/46 reads (48%) | catalogued as COSV51420697; called by muse, mutect2, varscan2
- ADGRL3 | c.2148A>G p.P716= (on ENST00000506720 / NM_001322402.2; = p.P648= on NM_015236.6) | Silent (SNP) | VAF 58/130 reads (45%) | called by muse, varscan2
- CHAD | c.462C>T p.L154= | Silent (SNP) | VAF 15/283 reads (5%) | called by muse, mutect2
- CSTF3 | c.2052C>G p.V684= | Silent (SNP) | VAF 6/152 reads (4%) | called by muse, mutect2
- DHX9 | c.2001G>A p.Q667= | Silent (SNP) | VAF 47/259 reads (18%) | catalogued as COSV62362436; called by muse, mutect2, varscan2
- DOLPP1 | c.228C>T p.I76= | Silent (SNP) | VAF 14/160 reads (9%) | called by muse, mutect2
- EFCAB5 | c.3396C>T p.I1132= | Silent (SNP) | VAF 3/32 reads (9%) | catalogued as COSV57929454; called by muse, mutect2
- EMP2 | c.240C>T p.F80= | Silent (SNP) | VAF 6/110 reads (5%) | called by muse, mutect2
- GNB2 | c.756C>G p.L252= | Silent (SNP) | VAF 26/345 reads (8%) | called by muse, mutect2
- GORASP1 | c.315C>T p.F105= | Silent (SNP) | VAF 120/325 reads (37%) | called by muse, mutect2, varscan2
- JUND | c.840C>A p.I280= | Silent (SNP) | VAF 59/217 reads (27%) | called by muse, mutect2, varscan2
- KLKB1 | c.1707G>T p.G569= | Silent (SNP) | VAF 25/96 reads (26%) | called by muse, mutect2, varscan2
- LRRCC1 | c.333G>A p.L111= | Silent (SNP) | VAF 18/84 reads (21%) | called by muse, mutect2, varscan2
- MTMR9 | c.12G>A p.A4= | Silent (SNP) | VAF 9/81 reads (11%) | called by muse, mutect2, varscan2
- ODC1 | c.159G>A p.L53= | Silent (SNP) | VAF 24/82 reads (29%) | catalogued as COSV52171339; called by muse, mutect2, varscan2
- PPARGC1B | c.1902C>T p.L634= | Silent (SNP) | VAF 22/393 reads (6%) | catalogued as COSV58525998; called by muse, mutect2
- PSIP1 | c.249G>A p.E83= | Silent (SNP) | VAF 14/42 reads (33%) | called by muse, mutect2, varscan2
- SEMA3G | c.1956C>T p.T652= | Silent (SNP) | VAF 78/235 reads (33%) | called by muse, mutect2, varscan2
- SREK1 | c.1347G>A p.E449= | Silent (SNP) | VAF 55/467 reads (12%) | catalogued as COSV99398481; called by muse, mutect2, varscan2
- SSH1 | c.2451G>A p.Q817= | Silent (SNP) | VAF 58/125 reads (46%) | catalogued as COSV58457944; called by muse, mutect2, varscan2
- TRBV10-2 | c.186G>A p.L62= | Silent (SNP) | VAF 47/130 reads (36%) | called by muse, mutect2, varscan2
- WDFY4 | c.2658C>T p.L886= | Silent (SNP) | VAF 29/106 reads (27%) | called by muse, mutect2, varscan2
- ABCA7 | c.161-58G>A | Intron (SNP) | VAF 19/45 reads (42%) | catalogued as rs1270919526; called by muse, mutect2, varscan2
- ABCD2 | c.*153C>G | 3'UTR (SNP) | VAF 90/173 reads (52%) | called by muse, mutect2, varscan2
- ABHD2 | c.*5855C>T | 3'UTR (SNP) | VAF 9/193 reads (5%) | called by muse, mutect2
- AC012236.1 | n.543T>G | RNA (SNP) | VAF 13/24 reads (54%) | catalogued as rs976228387; called by muse, mutect2, varscan2
- ASH2L | chr8:38105502 G>A | 5'Flank (SNP) | VAF 86/98 reads (88%) | catalogued as rs1385514420; called by muse, mutect2, varscan2
- B3GLCT | c.*944C>T | 3'UTR (SNP) | VAF 43/66 reads (65%) | called by muse, mutect2, varscan2
- BRWD1 | c.6571+291G>A | Intron (SNP) | VAF 26/562 reads (5%) | called by muse, mutect2
- C16orf72 | c.-380C>A | 5'UTR (SNP) | VAF 27/64 reads (42%) | called by muse, mutect2, varscan2
- CA1 | c.*6C>T | 3'UTR (SNP) | VAF 22/724 reads (3%) | called by muse, mutect2
- CAPZA1 | c.39+71G>A | Intron (SNP) | VAF 47/108 reads (44%) | called by muse, mutect2, varscan2
- CCN1 | c.63+42C>T | Intron (SNP) | VAF 18/357 reads (5%) | called by muse, mutect2
- CD4 | c.*110C>T | 3'UTR (SNP) | VAF 27/238 reads (11%) | catalogued as COSV99163747; called by mutect2, varscan2
- CHCHD1 | c.243+301C>T | Intron (SNP) | VAF 45/135 reads (33%) | called by muse, mutect2, varscan2
- COBL | c.*828G>A | 3'UTR (SNP) | VAF 25/180 reads (14%) | called by muse, mutect2, varscan2
- COPZ1 | c.487-284C>T | Intron (SNP) | VAF 24/73 reads (33%) | catalogued as rs908151598; called by muse, mutect2, varscan2
- CREG2 | c.*215G>A | 3'UTR (SNP) | VAF 62/123 reads (50%) | catalogued as rs960366053; called by muse, mutect2, varscan2
- CSMD3 | c.*186G>T | 3'UTR (SNP) | VAF 5/83 reads (6%) | called by muse, mutect2
- DAAM2 | c.2061-185C>T | Intron (SNP) | VAF 3/12 reads (25%) | called by muse, mutect2
- DCN | c.211+1280G>A | Intron (SNP) | VAF 17/280 reads (6%) | called by muse, mutect2
- DEPDC1 | c.*2160G>A | 3'UTR (SNP) | VAF 64/191 reads (34%) | called by muse, mutect2, varscan2
- EAF2 | c.-18C>T | 5'UTR (SNP) | VAF 24/358 reads (7%) | called by muse, mutect2
- EIF4A2 | c.209-51G>C | Intron (SNP) | VAF 11/246 reads (4%) | called by muse, mutect2
- FAM126B | c.*586C>T | 3'UTR (SNP) | VAF 45/83 reads (54%) | called by muse, mutect2, varscan2
- FAM161A | c.*19C>G | 3'UTR (SNP) | VAF 106/258 reads (41%) | called by muse, varscan2
- FAN1 | c.1577+90A>C | Intron (SNP) | VAF 9/14 reads (64%) | called by muse, mutect2, varscan2
- FHL2 | c.-127G>A | 5'UTR (SNP) | VAF 79/168 reads (47%) | called by muse, mutect2, varscan2
- FLRT2 | c.*1298C>T | 3'UTR (SNP) | VAF 13/128 reads (10%) | called by mutect2, varscan2
- FPGT-TNNI3K | c.2114+2441T>C | Intron (SNP) | VAF 4/82 reads (5%) | catalogued as rs981838039; called by muse, mutect2
- FST | c.*542G>A | 3'UTR (SNP) | VAF 23/145 reads (16%) | called by muse, mutect2, varscan2
- GAPVD1 | c.1441+1038A>T | Intron (SNP) | VAF 64/147 reads (44%) | called by muse, mutect2, varscan2
- GNAI3 | c.*6620C>A | 3'UTR (SNP) | VAF 45/137 reads (33%) | called by muse, mutect2, varscan2
- GORASP1 | c.916+133C>T | Intron (SNP) | VAF 62/147 reads (42%) | called by muse, mutect2, varscan2
- GRIA3 | c.268+18595C>G | Intron (SNP) | VAF 40/55 reads (73%) | catalogued as rs1221237408; called by muse, mutect2, varscan2
- GTPBP10 | c.*6126G>A | 3'UTR (SNP) | VAF 12/30 reads (40%) | called by muse, mutect2, varscan2
- GUCY1A2 | c.*662G>A | 3'UTR (SNP) | VAF 25/92 reads (27%) | called by muse, mutect2, varscan2
- HHIPL1 | c.*4014C>G | 3'UTR (SNP) | VAF 5/92 reads (5%) | called by muse, mutect2
- KLC1 | c.*9725C>G | 3'UTR (SNP) | VAF 84/180 reads (47%) | called by muse, mutect2, varscan2
- KMO | c.*3433G>A | 3'UTR (SNP) | VAF 58/159 reads (36%) | called by muse, mutect2, varscan2
- LINC01555 | n.824G>C | RNA (SNP) | VAF 67/148 reads (45%) | called by muse, mutect2, varscan2
- MAN2A1 | c.-901C>T | 5'UTR (SNP) | VAF 50/93 reads (54%) | called by muse, mutect2, varscan2
- MARCHF1 | c.*824A>T | 3'UTR (SNP) | VAF 56/121 reads (46%) | called by muse, mutect2, varscan2
- MBTPS2 | c.*141C>T | 3'UTR (SNP) | VAF 5/55 reads (9%) | called by muse, mutect2, varscan2
- MEDAG | c.-35C>T | 5'UTR (SNP) | VAF 14/19 reads (74%) | called by muse, mutect2, varscan2
- MGST3 | chr1:165655662 G>A | 3'Flank (SNP) | VAF 161/495 reads (33%) | called by muse, mutect2, varscan2
- NEK11 | c.*326G>C | 3'UTR (SNP) | VAF 29/85 reads (34%) | called by muse, mutect2, varscan2
- NPAS3 | c.558+75G>T | Intron (SNP) | VAF 67/153 reads (44%) | catalogued as rs1212025506; called by muse, mutect2, varscan2
- NPHP3 | c.393+63C>T | Intron (SNP) | VAF 49/146 reads (34%) | catalogued as rs1480514078; called by muse, mutect2, varscan2
- NTRK2 | c.1585+5533A>C | Intron (SNP) | VAF 42/83 reads (51%) | called by muse, mutect2, varscan2
- PGAP4 | c.*1816G>A | 3'UTR (SNP) | VAF 56/157 reads (36%) | called by muse, mutect2, varscan2
- PHACTR1 | c.-27C>G | 5'UTR (SNP) | VAF 63/233 reads (27%) | catalogued as rs751026504; called by muse, mutect2, varscan2
- PI4KAP2 | n.3001G>A | RNA (SNP) | VAF 33/86 reads (38%) | catalogued as rs765454737; called by muse, mutect2, varscan2
- PPP3R2 | c.*1632C>G | 3'UTR (SNP) | VAF 45/95 reads (47%) | called by muse, mutect2, varscan2
- PRR14 | c.-50-34C>T | Intron (SNP) | VAF 6/14 reads (43%) | called by muse, mutect2, varscan2
- PSMA3 | c.590+150G>A | Intron (SNP) | VAF 8/19 reads (42%) | catalogued as rs371178228; called by muse, mutect2, varscan2
- PYCR2 | c.*298C>T | 3'UTR (SNP) | VAF 65/241 reads (27%) | called by muse, mutect2, varscan2
- RALY | c.876+71G>C | Intron (SNP) | VAF 6/59 reads (10%) | called by muse, mutect2
- RALYL | c.*884G>A | 3'UTR (SNP) | VAF 20/67 reads (30%) | called by muse, mutect2, varscan2
- RASGRP3 | c.1278+61T>A | Intron (SNP) | VAF 21/51 reads (41%) | called by muse, mutect2
- RBM27 | c.*1649C>G | 3'UTR (SNP) | VAF 25/106 reads (24%) | called by muse, mutect2, varscan2
- RIPK1 | c.*255G>A | 3'UTR (SNP) | VAF 7/41 reads (17%) | called by muse, mutect2, varscan2
- S1PR3 | c.-148+2804T>A | Intron (SNP) | VAF 59/142 reads (42%) | called by muse, mutect2, varscan2
- SAP130 | c.*773G>C | 3'UTR (SNP) | VAF 25/65 reads (38%) | catalogued as rs909381500; called by muse, mutect2, varscan2
- SIAE | c.*3761C>T | 3'UTR (SNP) | VAF 9/131 reads (7%) | called by muse, mutect2
- SKP2 | c.8+31G>A | Intron (SNP) | VAF 115/404 reads (28%) | called by muse, mutect2, varscan2
- SLC16A2 | c.*754C>T | 3'UTR (SNP) | VAF 7/80 reads (9%) | called by muse, mutect2
- SLC30A6 | c.*2667C>T | 3'UTR (SNP) | VAF 24/163 reads (15%) | called by muse, mutect2, varscan2
- SLC35D1 | c.*4614G>A | 3'UTR (SNP) | VAF 42/157 reads (27%) | called by muse, mutect2, varscan2
- SNX19 | c.*1112G>C | 3'UTR (SNP) | VAF 7/174 reads (4%) | called by muse, mutect2
- SOCS5 | c.*1001C>T | 3'UTR (SNP) | VAF 54/175 reads (31%) | called by muse, mutect2, varscan2
- SOCS5 | c.*1754C>G | 3'UTR (SNP) | VAF 31/95 reads (33%) | called by muse, mutect2, varscan2
- SPATA13 | c.*407C>T | 3'UTR (SNP) | VAF 42/352 reads (12%) | called by muse, mutect2, varscan2
- ST6GAL2 | c.*1526A>C | 3'UTR (SNP) | VAF 56/126 reads (44%) | called by muse, mutect2, varscan2
- STYX | c.*3047C>T | 3'UTR (SNP) | VAF 7/136 reads (5%) | called by muse, mutect2
- TAT | c.*701C>T | 3'UTR (SNP) | VAF 5/43 reads (12%) | called by muse, mutect2
- TFAM | c.-5G>C | 5'UTR (SNP) | VAF 16/339 reads (5%) | called by muse, mutect2
- TMEM106A | c.275+39C>A | Intron (SNP) | VAF 58/140 reads (41%) | called by muse, mutect2, varscan2
- TMEM236 | c.*386C>T | 3'UTR (SNP) | VAF 24/196 reads (12%) | called by muse, mutect2, varscan2
- TMEM268 | c.*2560C>G | 3'UTR (SNP) | VAF 46/104 reads (44%) | called by muse, varscan2
- TNS3 | c.4194-835C>T | Intron (SNP) | VAF 91/273 reads (33%) | catalogued as rs1185574707; called by muse, mutect2, varscan2
- TOX | c.*2089G>A | 3'UTR (SNP) | VAF 12/284 reads (4%) | called by muse, mutect2
- TSGA13 | c.*188G>A | 3'UTR (SNP) | VAF 5/70 reads (7%) | called by muse, mutect2
- TSHR | c.692+381C>T | Intron (SNP) | VAF 57/134 reads (43%) | called by muse, mutect2, varscan2
- TTN | c.35375-500G>A | Intron (SNP) | VAF 24/73 reads (33%) | called by muse, mutect2, varscan2
- TUT1 | c.1474+107G>A | Intron (SNP) | VAF 5/44 reads (11%) | catalogued as rs1348624589; called by muse, mutect2
- UGT2B10 | c.*186C>T | 3'UTR (SNP) | VAF 65/209 reads (31%) | catalogued as rs969192286, COSV99608148; called by muse, mutect2, varscan2
- UVSSA | c.*8801C>G | 3'UTR (SNP) | VAF 42/88 reads (48%) | called by muse, varscan2
- VGLL3 | c.*5012T>C | 3'UTR (SNP) | VAF 29/56 reads (52%) | called by muse, mutect2, varscan2
- VSTM2A | c.*1770G>A | 3'UTR (SNP) | VAF 35/111 reads (32%) | catalogued as rs943224985; called by muse, mutect2, varscan2
- WHRN | c.-460C>A | 5'UTR (SNP) | VAF 7/133 reads (5%) | called by muse, mutect2
- ZBTB22 | c.*231G>A | 3'UTR (SNP) | VAF 86/230 reads (37%) | called by muse, varscan2
- ZFAND2B | c.-125G>C | 5'UTR (SNP) | VAF 13/34 reads (38%) | catalogued as COSV54698957; called by muse, mutect2
- ZFP37 | c.*2018C>G | 3'UTR (SNP) | VAF 48/109 reads (44%) | called by muse, mutect2, varscan2
- ZFP37 | c.*1925C>A | 3'UTR (SNP) | VAF 42/98 reads (43%) | called by muse, mutect2, varscan2
- ZNF648 | c.*1675G>A | 3'UTR (SNP) | VAF 17/107 reads (16%) | called by muse, mutect2, varscan2
- ZNF662 | c.*545C>G | 3'UTR (SNP) | VAF 49/193 reads (25%) | called by muse, mutect2, varscan2
- ZSWIM8 | c.4651-231G>A | Intron (SNP) | VAF 33/68 reads (49%) | catalogued as COSV55212738; called by muse, mutect2, varscan2
- ZXDB | c.*2820G>A | 3'UTR (SNP) | VAF 36/73 reads (49%) | called by muse, mutect2, varscan2
